Surgical pathology report (de-identified scan), TCGA case TCGA-EA-A5O9, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Asterand, specimen TCGA-EA-A5O9-01A (Primary Tumor).

Gross Description: There is an uterus with cervix, fragment of vagina, adnexa and fatty tissue fragments. Vagina is of normal structure. Exocervix is replaced by the saucer-like tumor up to 7 x 5.5 cm in size, 1.5 cm thick. Tumor spreads along the surface to the endocervix. Endometrium is of normal structure. Ovaries are with small hyperemic cysts. Fallopian tubes are of normal structure. Fatty tissue demonstrated hyperemia.

Microscopic Description: Squamous cell carcinoma of the cervix, G-2, with superficial spread to the endocervix. Tumor size is 7 x 5.5 cm. Tumor thickness is 1.5 cm. Vagina is of normal structure. Endometrium is of secretory type. Ovaries are with luteal body (left ovary), fibrous bodies, follicular cysts. Fallopian tubes are hyperemic. Examined lymph nodes demonstrated hyperemia, lipomatosis, fibrosis.

Diagnosis Details: Tumor Features: Ulcerated, Tumor Extent: Lesion greater than 4.0cm, Venous Invasion: Absent, Margins: Absent, Treatment Effect:

Comments:

Formatted Path Reports: CERVIX TISSUE CHECKLIST

Specimen type: Radical hysterectomy

Tumor site: Exocervix

Tumor size: 5.5 x 1.5 x 7 cm

Histologic type: Squamous cell carcinoma

Histologic grade: Moderately differentiated

Tumor extent: Lesion greater than 4.0 cm

Lymph nodes: 0/10 positive for metastasis (Pelvic 0/10)

Lymphatic invasion: Not specified

Venous invasion: Absent

Margins: Uninvolved

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: None

ICD-0-3
Carcinoma, Squamous cell
NOS
8070/3,
Site: Cervix Uteri, exocervix
C53.1
JW 2/1/13

HPV A Discrepancy		☒
Non-Malignancy History		☒

Source: NCI Genomic Data Commons file 34c3ab60-3efc-46f6-bed8-faa22efbee3a (TCGA-EA-A5O9.289C553F-685F-4308-B429-C741585BD25F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).